Somatic mutation profile of tumor specimen TCGA-VQ-AA6G-01A (aliquot TCGA-VQ-AA6G-01A-11D-A410-08) from TCGA case TCGA-VQ-AA6G, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 68.7 years (25,091 days).
Specimen TCGA-VQ-AA6G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 788d4275-ac37-4d4d-952f-672afc3889f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-AA6G-10A (Blood Derived Normal), aliquot TCGA-VQ-AA6G-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a89a802-3a9d-404a-a605-e549991e025a

The open-access MAF lists 137 somatic variants for this specimen: 104 protein-altering or splice-affecting, 28 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 28, Nonsense Mutation 8, Frame Shift Del 4, RNA 3, Intron 1, In Frame Del 1, 5'UTR 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.4226G>T p.R1409L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs142258568, COSV99288928; called by muse, mutect2, varscan2
- ABCC2 | c.4183C>T p.L1395F | Missense Mutation (SNP) | VAF 79/251 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100966613; called by muse, mutect2, varscan2
- ADAD2 | c.1319C>T p.A440V (on ENST00000315906 / NM_001145400.2; = p.A522V on NM_139174.4) | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.068); catalogued as COSV99235454; called by muse, mutect2, varscan2
- ADAMTS5 | c.1469C>T p.T490I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.144); catalogued as COSV99537930; called by muse, mutect2, varscan2
- ADAMTS9 | c.476A>C p.N159T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1427389525, COSV99899826; called by muse, mutect2, varscan2
- ADGRF5 | c.2870G>T p.W957L | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99345976; called by muse, mutect2, varscan2
- ANKRD44 | c.1084G>C p.G362R | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV99985433; called by muse, mutect2, varscan2
- ANKS4B | c.691A>G p.M231V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV100289883; called by muse, mutect2, varscan2
- AQP12A | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs566667626; called by muse, mutect2, varscan2
- ARHGAP33 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs774765746, COSV50148774, COSV99140930; called by muse, mutect2, varscan2
- ASAP3 | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371915285; called by muse, mutect2, varscan2
- ASTN1 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs866568425, COSV99920448, COSV99922367; called by muse, mutect2, varscan2
- BAIAP3 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs148280808; called by muse, mutect2, varscan2
- BCLAF1 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs771321542, COSV100786499, COSV100786785; called by muse, mutect2
- C1orf210 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.044); catalogued as rs897390048, COSV101382217; called by muse, mutect2, varscan2
- CA10 | c.672A>C p.E224D | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV99563893; called by muse, mutect2, varscan2
- CASKIN1 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100624251; called by muse, mutect2, varscan2
- CCKBR | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs145658504; called by muse, mutect2, varscan2
- CDH2 | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV52296651; called by muse, mutect2, varscan2
- CNTNAP2 | c.3382-1G>T p.X1128_splice | Splice Site (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100668238, COSV62183104; called by muse, mutect2, varscan2
- COL6A6 | c.2795C>T p.T932M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs377667400; called by muse, mutect2, varscan2
- COPG1 | c.2008A>G p.N670D | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.935); catalogued as COSV100135759; called by muse, mutect2, varscan2
- CORO1B | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs754610168, COSV100396644; called by muse, varscan2
- CYFIP2 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV59038736; called by muse, mutect2, varscan2
- CYP2E1 | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV99429119; called by muse, mutect2, varscan2
- CYP4F8 | c.1385C>A p.S462* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as rs1190402029, COSV100358121, COSV100358167; called by muse, mutect2, varscan2
- DPPA2 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.778); catalogued as rs199811743; called by muse, mutect2, varscan2
- DSPP | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.039); catalogued as rs370086773, COSV99217617; called by muse, mutect2, varscan2
- FBXL4 | c.259A>C p.S87R | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.134); catalogued as COSV57746255; called by muse, mutect2, varscan2
- FBXO7 | c.1498G>A p.G500S | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs113341800, COSV99832784; called by muse, mutect2, varscan2
- GOLGA6B | c.851A>C p.K284T | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101406930; called by muse, mutect2, varscan2
- GOLGB1 | c.4462G>A p.A1488T | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1033749244, COSV100511178; called by muse, mutect2, varscan2
- GPR156 | c.1619G>A p.R540Q | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs770848759, COSV100251545; called by muse, mutect2, varscan2
- GRXCR1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs200231391, COSV101295719, COSV67674982; called by muse, mutect2, varscan2
- HLA-F | c.885G>A p.W295* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99466054, COSV99466162; called by muse, mutect2
- HOXD3 | c.247G>T p.G83* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99980301; called by muse, mutect2, varscan2
- IGKV1D-8 | c.210C>G p.I70M | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs752522645; called by muse, mutect2, varscan2
- IL16 | c.2955C>A p.S985R (on ENST00000302987 / NM_172217.5; = p.S284R on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100267834; called by muse, mutect2, varscan2
- IPO13 | c.1235G>A p.W412* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100961267; called by muse, mutect2
- JAG1 | c.1223C>T p.T408M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773039210, COSV99653189; called by muse, mutect2, varscan2
- KCNH5 | c.132T>A p.N44K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100527269; called by muse, mutect2, varscan2
- KCNJ2 | c.999G>T p.E333D | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV99696434; called by muse, mutect2, varscan2
- KIF20A | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101203148, COSV99073145; called by muse, mutect2, varscan2
- KIF27 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141363838; called by muse, mutect2, varscan2
- KNTC1 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); catalogued as COSV100338522; called by muse, mutect2, varscan2
- KRTAP13-1 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV100819887; called by muse, mutect2, varscan2
- LCE1B | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.873); catalogued as COSV100780297, COSV63980543; called by muse, mutect2, varscan2
- LRP1B | c.9232A>G p.S3078G | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV101258019; called by muse, mutect2, varscan2
- LRRK2 | c.804A>C p.E268D | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV100110720; called by muse, mutect2, varscan2
- LRRK2 | c.7493T>C p.I2498T | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100110723; called by muse, mutect2, varscan2
- MARCHF4 | c.424_426del p.E142del | In Frame Del (DEL) | VAF 5/32 reads (16%) | catalogued as rs763759229; called by mutect2, pindel
- MTOR | c.3607C>T p.R1203* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as COSV63871687; called by muse, mutect2, varscan2
- MUC16 | c.24029C>A p.A8010E | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.263); catalogued as rs750483248, COSV101201352, COSV67495575; called by muse, mutect2, varscan2
- MYH13 | c.4622A>G p.K1541R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV99354621; called by muse, mutect2, varscan2
- NFE2 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1272443561, COSV56455813; called by muse, mutect2, varscan2
- OR13C2 | c.334T>C p.C112R | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV101604883; called by muse, mutect2
- OR1K1 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.774); catalogued as rs138952318; called by muse, varscan2
- PCDH10 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as rs750931587, COSV99993998; called by muse, mutect2, varscan2
- PCDHA7 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100971623; called by muse, mutect2, varscan2
- PDHA2 | c.923T>G p.V308G | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99757058; called by muse, mutect2, varscan2
- PDZD8 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100559571; called by muse, mutect2
- PHLPP1 | c.4169G>A p.R1390H | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs554336811, COSV53026998; called by muse, varscan2
- PIDD1 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs1565066449, COSV100758703; called by muse, mutect2, varscan2
- PIGM | c.769A>G p.T257A | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as rs770272554, COSV100928050; called by muse, mutect2, varscan2
- PIK3C2A | c.5021C>T p.T1674M | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs747006507, COSV99790967; called by muse, mutect2, varscan2
- PNLIPRP2 | c.921C>A p.Y307* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100077871, COSV53946592; called by muse, mutect2
- POMGNT1 | c.702G>A p.W234* | Nonsense Mutation (SNP) | VAF 22/67 reads (33%) | catalogued as COSV100915693; called by muse, mutect2, varscan2
- POU3F2 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100098958; called by muse, mutect2, varscan2
- PRAMEF15 | c.1263T>G p.S421R | Missense Mutation (SNP) | VAF 98/339 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1211299281; called by muse, mutect2, varscan2
- RFX2 | c.1906G>A p.G636S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1451726608, COSV100353892; called by muse, mutect2, varscan2
- RPRD2 | c.2465A>G p.Y822C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV100955193; called by muse, mutect2
- SEC16A | c.4838C>T p.S1613L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs554095424, COSV99259300; called by muse, mutect2, varscan2
- SLC28A2 | c.1539G>T p.W513C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100754761, COSV100754840; called by muse, mutect2, varscan2
- SLC2A14 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as rs948978048, COSV61586212; called by muse, mutect2, varscan2
- SLC32A1 | c.1321G>A p.V441I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.183); catalogued as rs777043497, COSV99462474; called by muse, mutect2, varscan2
- STAT5B | c.172A>C p.T58P | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.405); catalogued as COSV99511100; called by muse, mutect2, varscan2
- STT3A | c.1789C>A p.L597I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as rs1315979409, COSV67064433, COSV67065483; called by muse, mutect2, varscan2
- SV2A | c.898T>C p.W300R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100975212; called by muse, mutect2, varscan2
- SYNGR3 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.488); catalogued as COSV50191623; called by mutect2, varscan2
- TAF4B | c.361A>C p.S121R | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99300578; called by muse, mutect2, varscan2
- TENM4 | c.7985G>A p.R2662H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs369788944; called by muse, mutect2, varscan2
- TEX55 | c.518G>T p.R173I | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99817639; called by muse, mutect2
- TG | c.3710C>A p.P1237H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as COSV99601900; called by muse, mutect2, varscan2
- TRAF3 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as COSV100693667; called by muse, mutect2, varscan2
- TTN | c.18986G>T p.C6329F (on ENST00000591111; = p.C5402F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/140 reads (33%) | PolyPhen probably damaging (0.999); catalogued as COSV100620377; called by muse, mutect2, varscan2
- TTN | c.12996G>T p.K4332N (on ENST00000591111; = p.K4286N on NM_003319.4) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100620378; called by muse, mutect2, varscan2
- TTYH2 | c.1288G>T p.D430Y | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99483105; called by muse, mutect2
- UMODL1 | c.1226A>C p.H409P | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.612); catalogued as COSV61159976; called by muse, mutect2, varscan2
- USP43 | c.3277C>T p.P1093S | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV53300203; called by muse, mutect2, varscan2
- VPS13A | c.5084T>A p.L1695* | Nonsense Mutation (SNP) | VAF 24/80 reads (30%) | catalogued as COSV100653094; called by muse, mutect2, varscan2
- WDR82 | c.109A>T p.I37F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99626998; called by muse, mutect2, varscan2
- WNT3A | c.1033G>A p.V345I | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as rs375339690, COSV99469792; called by muse, varscan2
- ZNF366 | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.603); catalogued as rs766772853, COSV100574332; called by muse, mutect2, varscan2
- ZNF429 | c.353A>G p.K118R | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.324); catalogued as COSV100641983; called by muse, mutect2, varscan2
- ZNF500 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as rs543973140, COSV99556425; called by muse, varscan2
- ZNF598 | c.2462C>T p.T821M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs762159699, COSV99937318; called by muse, mutect2, varscan2
- ZNF658 | c.749A>G p.K250R | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.346); catalogued as rs751762191; called by muse, mutect2, varscan2
- ACO2 | c.2018_2024del p.H673Lfs*25 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- CRYBG3 | c.6527del p.P2176Qfs*23 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel, varscan2
- GABBR2 | c.1302C>A p.S434R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- GPRC6A | c.1529dup p.N510Kfs*2 | Frame Shift Ins (INS) | VAF 16/60 reads (27%) | called by mutect2, pindel, varscan2
- STK31 | c.2079_2089del p.S694Efs*5 | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | called by mutect2, pindel, varscan2
- ZFP36 | c.456_457del p.C153Sfs*22 (on ENST00000594442; = p.C147Sfs*22 on NM_003407.5) | Frame Shift Del (DEL) | VAF 32/117 reads (27%) | called by pindel, varscan2
- ADAMTS5 | c.2328C>T p.A776= | Silent (SNP) | VAF 33/122 reads (27%) | catalogued as rs1435477482, COSV99537928; called by muse, mutect2, varscan2
- ASXL2 | c.1866G>A p.P622= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs372643334; called by muse, mutect2, varscan2
- CD163 | c.1602A>C p.G534= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100775985; called by muse, mutect2, varscan2
- CHRNB4 | c.414C>T p.N138= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs55851389; called by muse, mutect2, varscan2
- CTNND2 | c.2617T>C p.L873= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs775420264, COSV58877880, COSV58910673; called by muse, mutect2
- DNAH8 | c.72C>T p.C24= | Silent (SNP) | VAF 44/87 reads (51%) | catalogued as rs1228961346, COSV100546270; called by muse, mutect2, varscan2
- FOXF2 | c.627C>T p.R209= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs1420708238, COSV99453358; called by muse, mutect2, varscan2
- FUT1 | c.420G>A p.P140= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as rs1411517606, COSV100038186; called by muse, mutect2, varscan2
- GPATCH8 | c.1116A>G p.S372= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as COSV100132733; called by muse, mutect2
- GSTA2 | c.75A>T p.A25= | Silent (SNP) | VAF 81/135 reads (60%) | catalogued as COSV101534054; called by muse, mutect2, varscan2
- H1-0 | c.126C>T p.R42= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs758978049, COSV50648649; called by muse, mutect2, varscan2
- ITGA5 | c.1068C>T p.D356= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs774155456, COSV53217545; called by muse, mutect2, varscan2
- KLHL2 | c.966T>C p.S322= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV99900085; called by muse, mutect2, varscan2
- LPL | c.105C>T p.I35= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as rs145405273; called by muse, mutect2, varscan2
- NALCN | c.1893G>T p.L631= | Silent (SNP) | VAF 41/188 reads (22%) | catalogued as COSV99216305; called by muse, mutect2, varscan2
- NLE1 | c.858C>T p.H286= | Silent (SNP) | VAF 9/167 reads (5%) | catalogued as COSV100681044; called by muse, mutect2
- OR2G3 | c.279T>G p.T93= | Silent (SNP) | VAF 50/171 reads (29%) | catalogued as COSV60680716, COSV60681025; called by muse, mutect2, varscan2
- OR4C3 | c.285C>T p.C95= | Silent (SNP) | VAF 42/138 reads (30%) | catalogued as rs758655627, COSV100168038; called by muse, mutect2, varscan2
- PCDHA3 | c.1845C>T p.T615= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as rs373825257, COSV100793463; called by muse, mutect2, varscan2
- PIPOX | c.993C>T p.L331= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as rs142726156; called by muse, mutect2, varscan2
- RUBCN | c.486C>T p.D162= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs745959907, COSV99584506; called by muse, mutect2, varscan2
- SLCO6A1 | c.528T>G p.A176= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV101134624; called by muse, mutect2, varscan2
- SORBS3 | c.1347G>A p.P449= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs750210348, COSV99531430; called by muse, mutect2, varscan2
- SUCO | c.2580T>G p.S860= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs1263002849, COSV99743189; called by muse, mutect2, varscan2
- TRIM42 | c.501G>A p.E167= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99648549; called by muse, mutect2, varscan2
- USP48 | c.1734T>A p.V578= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100379710, COSV100380048; called by mutect2, varscan2
- ZNF254 | c.523A>C p.R175= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV100741716; called by muse, mutect2, varscan2
- ZNF623 | c.15T>C p.S5= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV101513578; called by muse, mutect2
- DCHS2 | n.8588T>G | RNA (SNP) | VAF 6/120 reads (5%) | catalogued as COSV100602124; called by muse, mutect2
- ISCA1P1 | n.158G>A | RNA (SNP) | VAF 22/106 reads (21%) | catalogued as rs959771133; called by muse, mutect2, varscan2
- NBPF11 | c.-549+2404G>T | Intron (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- OPN5 | c.-1A>G | 5'UTR (SNP) | VAF 89/152 reads (59%) | catalogued as COSV100970533; called by muse, mutect2, varscan2
- SNORD116-5 | n.76T>C | RNA (SNP) | VAF 82/220 reads (37%) | called by muse, mutect2, varscan2
